MMRF case MMRF_2238 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/34221dd7-2cfa-4856-8ba5-a2e1e4c1f279

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.7 years (19,246 days); ISS stage: III; Days to last known disease status: 877 days (2.4 years); Days to last follow up: 877 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 27 days; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 141 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 143 days; Days to treatment end: 143 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 230 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 6 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.885 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 27.7 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 13.1 ×10⁹/L; Absolute Neutrophil 8.25 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 7.2 g/dL; Glucose 6.99 mmol/L; C-Reactive Protein 3.3 mg/dL.
- Day 118 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.897 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.845 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 5.28 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.18 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 189 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 2.95 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.34 mmol/L.
- Day 286 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 377 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.05 mmol/L.
- Day 433 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.01 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.79 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.94 mmol/L.
- Day 559 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.47 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 622 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.23 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 3.12 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.32 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 777 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 3.53 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 5.56 mmol/L.
- Day 877 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.31 mg/dL; Immunoglobulin G 9.37 g/L; Immunoglobulin A 3.42 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 6.16 mmol/L.

Other clinical attributes
- Day 6: Weight: 100 kg; Height: 198 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2238_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 6 days.
- Sample MMRF_2238_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 6 days.
